Surgical pathology report (de-identified scan), TCGA case TCGA-85-A4JC, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A4JC-01A (Primary Tumor).

[page 1 of 2]
Gross Description: Lobe with free lobar bronchus, with a parahilar tumoral structure of 7/6/7 cm in diameter, with necrosis and central ulceration; the tumor spreads to the periphery and retracts the visceral pleura; it is white with hotbeds of necrosis.

Microscopic Description: TUMOR FRAGMENT:

Bronchopulmonary neoplasm of epidermoid carcinoma type, G1, well differentiated, with keratinization and hotbeds of necrosis, formed of beaches of pleomorphic cellswith keratinization and parakeratosis, with fibrous-inflammatory stroma.

TUMOR FRAGMENT WITH PLEURA:

Fibrocollagenous pleura with inflammatory reaction, without tumoral infiltration; the juxta-pleural pulmonary parenchyma with tumoral infiltration of the epidermoid carcinoma.

LYMPH NODE STATION XI: No metastases.

Diagnosis Details:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 7 x 6 x 7 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Well differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/1 positive for metastasis (Interlobar 0/1)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

1CD-0-3

carcinoma, squamous cell, nos 8070/3
site: lung, upper lobe C34.1

hw
10/2/12

[page 2 of 2]
Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Left- upper

Case ID (circle):	QUALIFIED	

km /w 9/23/12

Source: NCI Genomic Data Commons file 2326c1ef-fba8-4e20-aaf6-a50d5dd48428 (TCGA-85-A4JC.A084BBE7-0EFB-4C9A-9A68-FB98C7CCA0BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).